CGCI case BLGSP-71-06-00013 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c3f876f4-2d3a-4d60-b6c4-019f94010330

Demographics
Sex at birth: male; Race: black or african american; Age at index: 5 years; Vital status: Dead; Days to death: 192 days.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bones of skull and face and associated joints; Classification of tumor: primary; Age at diagnosis: 5.2 years (1,902 days); Year of diagnosis: 2013; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 192 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Maxilla; Sites of involvement: Maxilla / Abdomen.
   Pathology details: Tumor largest dimension diameter: 7 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COM; Days to treatment start: 1 day; Days to treatment end: 15 days; Number of cycles: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 1 day; Days to treatment end: 15 days; Number of cycles: 2.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Follow-up contact recording only the day: day 192.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 350 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Weight: 15 kg; Height: 107 cm; BMI: 13.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00013-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen; Days to sample procurement: 0 days; Initial weight: 233 mg; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00013-01B-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 7; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
  Slide BLGSP-71-06-00013-01B-01-S1-HE: Section location: Top; Percent tumor cells: 93; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-06-00013-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00013-01-CD20-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD20: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-Ki67-1-20X: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD3: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD10-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD3-1-20X: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-BCL6: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-Ki67-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-HE-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD3-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-BCL2: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-Ki67: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-BCL6-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-BCL2-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-HE-1-20X: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-BCL6-1-20X: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-BCL2-1-20X: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD20-1-20X: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD10: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-HE: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-06-00013-01-CD10-1-20X: Tissue microarray coordinates: A2,E3,C5.
- Sample BLGSP-71-06-00013-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: intra abdominal mass on ultra sound; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 350; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 2.
